Surgical pathology report (de-identified scan), TCGA case TCGA-06-0875, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0875-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

06-0875

CLINICAL HISTORY

[REDACTED] with headache has posterior right frontal necrotic, enhancing tumor, with mass effect and edema.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy
B: Right frontal brain tumor

PATHOLOGICAL DIAGNOSIS:

- A. Brain, site not specified, excisional biopsy:
1. Glioblastoma.
2. MIB-1 proliferation index: 30%.

See Comment.

COMMENT

The sections contain portions of a malignant astrocytic neoplasm that has frequent small-multinucleated cells. There is nuclear anaplasia, brisk mitotic activity, microvascular cellular proliferation, vascular necrosis and thrombosis, and prominent karyorrhexis. The MIB-1 proliferation index is very high at about 30%.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was done on tissue block

[page 2 of 4]
TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S552, D19S219, D19S412, PLA2G4C

Results-Comments

Test performed on tumor paraffin block [REDACTED] and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[page 3 of 4]
INTRA-OPERATIVE CONSULTATION

A.

Brain, excision biopsy, touch prep and smears: Glioblastoma. Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

Received fresh, two fragments, 0.8 cm. in aggregate. Diffluent, grayish-glistening. In total, A1.

B.

SPECIMEN: Right frontal brain tumor.

FIXATIVE: None.

GENERAL: Received is a 2 x 0.5 x 0.3 cm. aggregate of irregular, pink-tan to pale yellow hemorrhagic soft tissue.

SECTIONS: B1 entirely submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates focal heavy glial fibrillogenesis by the neoplastic cells. About 2/3rds of the neoplastic cells strongly over express the p53 protein. The neuronal markers (NeuN and synaptophysin) demonstrate the infiltrative pattern of the neoplasm, but no clearly neoplastic neuronal component. With the MIB-1 there is a proliferation index of about 30% in the more active areas.

The immunoreresults are consistent with a high histological grade astrocytic neoplasm.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
TPS H/E x 1	1 [REDACTED]

Part B: Right frontal brain tumor

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
mGFAP-DA x 1	1 [REDACTED]
H/E x 1	1 [REDACTED]

[page 4 of 4]
MGMT x 1 1
Thanks.
MIB1-DA x 1 1
NeuN x 1 1
P53DO7 x 1 1
Synap-DA x 1 1

Do LOH (1p, 19q) also.

*** End of Report ***

Source: NCI Genomic Data Commons file f7390a8c-79a4-4b43-8704-ad455ed6a0b3 (TCGA-06-0875.1E48D17E-FEDA-4555-99EB-7E4744D79492.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).